Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-B055, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-B055-TTM2-A (Metastatic).

[page 1 of 13]
Pathology

DEPARTMENT OF PATHOLOGY

Page 1 of 2

Pathologist: [REDACTED]

Loc: [REDACTED]
Collected: [REDACTED] +13
Received: [REDACTED] +13

*****Addendum*****

CLINICAL HISTORY/DIAGNOSIS: Liver mass; prostate CA; sarcoidosis.

SPECIMEN SUBMITTED: Liver biopsy.

SURGICAL PATHOLOGY REPORT

DIAGNOSIS: Liver mass, needle biopsy:
- hepatocellular carcinoma.

GROSS DESCRIPTION: Received in formalin labeled [REDACTED] and "liver biopsy" are multiple (twelve) tan elongated tissue cores ranging from 0.1 to 2 cm in length and each less than 0.1 cm in diameter. The tissue is wrapped and submitted in toto in two.

Immediate evaluation of smears was performed by [REDACTED] to determine adequacy of material. The number of evaluations is one.

IMMEDIATE EVALUATION: Adequate [REDACTED]

[REDACTED] +13

MICROSCOPIC DESCRIPTION: Sections of biopsied liver have atypical hepatocytes with differentiation into acinar/glandular structures. No vascular invasion is seen. Lesional cells express Hep-1 and are negative for PSA by immunohistochemistry. Intradepartmental review performed.

[REDACTED] +14

Final Diagnosis performed by [REDACTED]

ADDENDUM: At the request of [REDACTED], this case has been forwarded to the [REDACTED] and was reviewed there by [REDACTED]. The diagnosis is as follows.

Liver mass, needle biopsy:

- moderately differentiated adenocarcinoma (see comment).

COMMENT: "Thank you for sending this case for consultation. The needle biopsy of the liver shows a moderately differentiated epithelial neoplasm which is characterized by large epithelioid cells with focal glandular formation. Adjacent non-neoplastic liver parenchyma shows nonspecific reactive changes. The tumor cells focally form anastomosing trabecular pattern which mimics hepatocellular carcinoma. The submitted immunoperoxidase stains show the tumor cells are positive for hepar-1, CK7, CK19, CK17, MOC31, S-100p, with cytoplasmic staining for CD10 and polyclonal CEA. The tumor cells are negative for CK20 and PSA. Immunoperoxidase stains performed on the submitted paraffin block show the tumor cells are positive for CDX2, but negative for glypican 3 and arginase. A mucicarmine stain is negative. The overall morphologic and immunophenotypical features support a diagnosis of moderately differentiated adenocarcinoma. Although tumor cells are positive

HISTOLOGY REPORT

[page 2 of 13]
Pathology

DEPARTMENT OF
PATHOLOGY

Page 2 of 2

for hepar-1, the staining of other hepatocellular markers including arginase, glypican 3, CD10, and polyclonal CEA, in conjunction with the morphology, argues against the diagnosis of hepatocellular carcinoma. The immunophenotypic features are indicative of a tumor arising in the pancreatobiliary tract including a primary cholangiocarcinoma or upper GI tract."

Note: The report and Comment were read and faxed to
+27

Final Diagnosis performed by +14
Addendum #1 performed by +27

[page 3 of 13]
pre-Baseline

Patient:

MRN:

DOB:

AGE:

Acct #:

Pt Outpatient

Class:

Adm:

D/C:

CSN:

LOC:

Accession #:

Date of completion:

CT ABDOMEN AND PELVIS W CONTRAST

Results

Status: Final result (Collected: +0

Exam Information

Status

Final

Exam

Begun

Exam

Ended

PACS Images

Show images for CT ABDOMEN AND PELVIS W CONTRAST

Narrative

OTHER PROVIDER:

CC:

EXAM DATE: +0

DOCUMENT STATUS: Final

PROCEDURE(S): CT ABDOMEN/PELVIS W CONTRAST

ORDER #:

RIGHT/LEFT:

PT. LOC:

OP

[page 4 of 13]
pre baseline

HISTORY: abdominal pain. fatigue. vomiting.

EXAM: CT ABDOMEN-PELVIS W CONT

COMPARISON: None available

Technique: Axial sections through the abdomen and pelvis were obtained following the administration of oral and 50 mL Visipaque 320 IV contrast. Delayed images were obtained. Coronal and sagittal reformats are produced.

Findings: 4 mm nodule along the major fissure on the right. Lung bases are otherwise clear. No discrete consolidation. No pleural effusion.

Hypodense liver lesions are present throughout the right lobe. The largest lesion in the inferior aspect of the right lobe of the liver measures approximately 3.5 cm in diameter. Additional smaller nodules are noted throughout the right lower liver.

A single radiodense stone is noted within the gallbladder lumen. No secondary signs of acute cholecystitis. The common bile duct is enlarged measuring approximately 15 mm in diameter.

The pancreas is atrophic. No pancreatic lesions are identified. The spleen is unremarkable. Normal adrenal glands.

The kidneys are atrophic. Bilateral renal cysts are present. No stones or hydronephrosis. Delayed imaging demonstrates normal renal excretion of contrast. The urinary bladder is grossly normal.

Large hiatal hernia. The small bowel is unremarkable. No evidence of small bowel obstruction. Normal appendix. Scattered diverticulosis without CT evidence of acute diverticulitis.

Multiple prominent retroperitoneal lymph nodes are noted. Nonspecific stranding in the mesentery. No definite free fluid. No free air. Postsurgical changes noted in the pelvis. Atherosclerotic changes are noted in the abdominal aorta.

Degenerative changes are noted in the lumbar spine. Sclerotic focus at T12 likely represents a bone island. Sclerotic bone metastases is not completely excluded.

Impression:

1. Cholelithiasis without CT evidence of acute cholecystitis. Additionally, the common bile duct is dilated. No evidence of

[page 5 of 13]
pancreatic mass.

pre baseline

2. Hypodense liver lesions are incompletely evaluated on this study. Comparison to prior images versus follow-up ultrasound or MRI may provide further evaluation.

3. Large hiatal hernia.

4. Prominent retroperitoneal lymph nodes. These are not enlarged by size criteria. This is a nonspecific finding.

5. Nonspecific fat stranding within the mesentery. No definite free fluid.

6. Sclerotic focus at T12. This likely represents a bone island, however, metastatic disease is not excluded.

Dictated: +0
Signed: +0

PAGE 2 of 2

Imaging

CT ABDOMEN AND PELVIS W CONTRAST (Order # [redacted] Imaging Information +0)

Signed by

Signed	Date/Time	Phone	Pager
[redacted]	[redacted]	[redacted]	[redacted]

Ordered On

Ordering Provider	Authorizing Provider	Ordering User	Ordering Department
[redacted]	[redacted]	[redacted]	[redacted]

Lab Information

[redacted]

External Result Report

External Result Report

Encounter

View Encounter

View SmartLink Info

CT ABDOMEN AND PELVIS W CONTRAST (Order # [redacted] +0)

[page 6 of 13]
ORDERING PROV:
ATTENDING PROV:
OTHER PROVIDER:
CC:

EXAM DATE: [REDACTED] +34 DOCUMENT STATUS: Final
PROCEDURE(S): NM TUMOR IMAGE PET/CT SKULL-THIGH
ORDER #: [REDACTED]

RIGHT/LEFT:

year of -1516

CLINICAL HISTORY: Non-small cell lung cancer [REDACTED] prostate cancer,
recently diagnosed liver cancer.

TECHNIQUE: PET images from the skull base to the distal thighs were
obtained following the intravenous administration of 9.7 mCi of 18
FDG. Low-dose noncontrast CT images were obtained and fused to the PET
study and reviewed on the MIMvista workstation. The patient's blood
glucose was 153 at the time of the exam.

CORRELATIVE IMAGING: CT of the abdomen and pelvis obtained on [REDACTED] +0
[REDACTED]

PREVIOUS STUDIES: None

FINDINGS:

Head and neck: Intense 18 FDG activity (SUVmax = 15.6) localizes to a
group of left supraclavicular lymph nodes measuring 3 cm in aggregate
lateral to the left thyroid lobe (image 37 of series 644).
Hypermetabolic lymph nodes are also noted in the left supraclavicular
region more laterally and at the level of the thoracic inlet above the
level of the aortic arch on the left (image 39 of series 604).

Chest: The distribution of 18 FDG activity in the chest appears
unremarkable. CT images reveal numerous small (6 mm or less)
noncalcified pulmonary nodules, the larger ones of which appear
cavitary (see images 38 or 63 of series 7 for example). All of these
nodules are below PET resolution.

Abdomen and pelvis: Intense 18 FDG activity localizes to multiple low
attenuating hepatic lesions noted on the recent CT, with SUV
measurements in the 10-11 range on a liver background averaging 5.
Several of the larger lesions appear to have a necrotic centers.

Intense 18 FDG activity localizes to multiple mesenteric and
retroperitoneal lymph nodes (see images 91 or 104 of series 604 for
example). CT images now reveal a stent within the common bile duct.
Postoperative changes consistent with prostate gland resection are
present. No abnormal activity in or adjacent to the surgical bed is
Continue on next page

Baseline

[page 7 of 13]
[REDACTED]

[REDACTED]

EXAM DATE: [REDACTED] +34
PROCEDURE(S) [REDACTED]

ORDER #: [REDACTED]

evident.

Musculoskeletal: The distribution of 18 FDG activity in the axial and proximal appendicular skeleton appears normal.

IMPRESSION: Normal study

1. Multiple hypermetabolic lesions are confirmed in the liver, the larger ones with central photopenia, consistent with necrosis.
2. Hypermetabolic lymph nodes are present in the left supraclavicular region, thoracic inlet, mesentery, and retroperitoneum.
3. Numerous small indeterminate pulmonary nodules are noted. The larger ones appear cavitary. Pulmonary metastatic disease is strongly suspected.

Electronically signed by: [REDACTED]

Dictated: [REDACTED]

Signed: [REDACTED] +34

[REDACTED]

PAGE 2 of 2

Baseline

[page 8 of 13]
Partial Response

Adm: +154
D/C: +154
CSN:

Department

Name	Address	Phone	Fax
------	---------	-------	-----

NM PET IMAGE W CT SKULL THIGH

Status: Final result

PACS Images

Show images for NM PET IMAGE W CT SKULL THIGH

Study Result

ORDERING PROV:

ATTENDING PROV:

OTHER PROVIDER:

CC:

EXAM DATE: +154

DOCUMENT STATUS: Final

PROCEDURE(S): NM TUMOR IMAGE PET/CT SKULL-THIGH

ORDER #:

RIGHT/LEFT:

HISTORY: stomach CA restaging

EXAM: NM PET TUMOR IMAGE W CT SKULL-THIGH FDG

PROCEDURE: 11.7 mCi of F-18 FDG was administered intravenously. Positron emission tomography was carried out from the skull base to the mid thigh. Simultaneous CT imaging was carried out for attenuation correction and anatomic correlation.

Blood Glucose: 128

Time from injection to imaging: 90 minutes.
+34

COMPARISON: PET/CT of PET Findings:

Neck findings: Currently, the metabolic activity is physiologic. The

[page 9 of 13]
Partial
Response

pathologic lymph node in the medial left supraclavicular fossa/level four lymph node station on previous examination has resolved.

Chest findings: The lymph node previously present in the left superior mediastinum has resolved. No lymphadenopathy is currently identified. The small nodules in the periphery of the superior segment right lower lobe and along the major fissure in the inferior central right lung field on previous examination are no longer identified. The lung parenchymal metabolic activity is physiologic.

Abdomen and pelvis findings: Intense activity seen along the large common bile duct stent. Gas is noted within the stent as well as the left hepatic lobe. No soft tissue mass can be identified adjacent to the stent. The previously seen metabolic lesions in the liver are no longer identified. The multiple pathologic metabolically active lymph nodes throughout the perirectal retroperitoneum and the root of the mesentery have reduced in size and now demonstrate no pathologic metabolic activity.

Moderate hiatal hernia. Diffuse diverticulosis.

Imaged extremities and osseous findings: Physiologic metabolic activity.

Impression:

1. Resolved pathologic metabolic activity and reduced size of the previously seen metastatic lesions of the inferior left neck, chest mediastinum, periaortic retroperitoneum, root of the abdominal mesentery as well as metastatic lesions throughout the liver.
2. Prior seen small nodules in the right lung are no longer identified.
3. Metabolic activity is present along the common bile duct stent without evidence of soft tissue mass on CT. This is nonspecific.

Electronically signed by: [REDACTED]

Dictated: [REDACTED]

Signed: [REDACTED]

+154

+154

PAGE 2 of 2

Imaging

NM PET IMAGE W CT SKULL THIGH (Order [REDACTED])

- Imaging Information

+154

Result History

NM PET IMAGE W CT SKULL THIGH (Order [REDACTED])

- Order Result History Report

+154

Signed by

Signed [REDACTED]

Date/Time [REDACTED]

Phone [REDACTED]

Pager [REDACTED]

+154

Exam Information

Status

Final [REDACTED]

Exam

Begun

Exam

Ended [REDACTED]

+154

[page 10 of 13]
ORDERING PROV: [REDACTED]
ATTENDING PROV: [REDACTED]
OTHER PROVIDER: [REDACTED]
CC: [REDACTED]
EXAM DATE: [REDACTED] +422 DOCUMENT STATUS: Final
PROCEDURE(S): NM TUMOR IMAGE PET/CT SKULL-THIGH
ORDER #: [REDACTED]

RIGHT/LEFT:

EXAM: NM PET TUMOR IMAGE W CT SKULL-THIGH FDG

CLINICIAN'S HISTORY: restage bladder

HISTORY REPORTED TO TECHNOLOGIST: Restaging metastatic biliary carcinoma postchemotherapy.

+359

+236

Comparison: PET CTs dated [REDACTED] and [REDACTED]

Procedure: Fluorine-18, 10.4 mCi was administered intravenously as fluorodeoxyglucose (FDG). Positron emission tomography was carried out from the skull base to the knees. Simultaneous CT imaging was carried out for attenuation correction and anatomic correlation.

The patients blood glucose level measured 135.

The radiotracer injection time to scan time was 88 minutes.

Findings:

Head and neck PET findings: Physiologic metabolic activity.

Head and neck CT findings: The unenhanced pharynx and larynx appear grossly normal. Vocal cords are symmetric. There is no neck lymphadenopathy.

Chest PET findings: Physiologic metabolic activity.

Chest CT findings: There is mild dependent atelectasis bilaterally. Lungs are otherwise clear. There is no pleural fluid. There is no pericardial fluid. The heart is normal size. There are coronary artery atherosclerotic calcifications. There is a moderate size hiatal hernia. There is no mediastinal or axillary lymphadenopathy.

Abdomen and pelvis PET findings: Physiologic metabolic activity.

Abdomen and pelvis CT findings: There is a biliary stent and a small amount of pneumobilia, also present previously. There is no discrete hepatic lesion. Bowel is nondistended. There are moderately dense

Continue on next page

Complete Response

[page 11 of 13]
[REDACTED]
[REDACTED]
EXAM DATE: [REDACTED] +422
PROCEDURE(S): [REDACTED]

peripheral aortic atherosclerotic calcifications.

Imaged extremities and osseous findings: Physiologic metabolic activity.

IMPRESSION: Stable examination without evidence of residual or recurrent tumor.

Electronically signed by: [REDACTED]

Dictated: [REDACTED]

Signed: [REDACTED] +422
[REDACTED] +422

Complete Response

[page 12 of 13]
DOS: [REDACTED] +768

Study: PET CT Skull Base to Mid-Thigh

STUDY: PET CT Skull Base to Mid-Thigh

IMPRESSION:

EXAM: NM PET TUMOR IMAGE W CT SKULL-THIGH FDG

CLINICIAN'S HISTORY: Malignant neoplasm of overlapping sites of biliary tract; Sec and unsp malig neoplasm of nodes of multiple regions

ADDITIONAL CLINICAL INDICATIONS: Restaging

COMPARISON: Prior PET/CT on [REDACTED] +608

TECHNIQUE: Whole-body PET/CT from the skull base through the upper thighs performed.

RADIOPHARMACEUTICAL: F-18 FDG

DOSE: 10.88 mCi

ROUTE OF ADMINISTRATION: Intravenous

LOCATION OF INJECTION (IF IV): Left antecubital

TIME FROM INJECTION TO IMAGING: 88 minutes

VIEWS OBTAINED: Axial, coronal, sagittal

PATIENT'S BLOOD GLUCOSE (IF APPLICABLE): 82

Latest Scan

[page 13 of 13]
Findings:

Neck: Physiologic distribution of glucose only. No enlarged cervical lymph nodes identified. Mucosal thickening of the maxillary sinuses.

Chest: Left-sided Mediport noted with the distal tip terminating in the distal SVC just above the cavoatrial junction. Moderate vascular calcification. Moderate size hiatal hernia, sliding type. Bilateral gynecomastia. No abnormal focal glucose accumulation. What appears related to surgical clips seen along the left infrahilar region are again noted.

Abdomen/pelvis: Common bile duct stent is in place. There is some increased activity along the distal common bile duct identified again although this has decreased in intensity and amount since prior study. Maximal SUV in this region is 5.7, previously 6.9.

The small hypodensity along the lateral aspect of the right hepatic lobe with adjacent capsular retraction is unchanged in appearance, again without abnormal glucose accumulation. There is a small amount of pneumobilia again noted extending into the left hepatic lobe, unchanged. Postsurgical changes status post prostatectomy again seen. There is moderate to advanced atherosclerotic disease. No enlarged lymph nodes are abnormal/suspicious glucose accumulation is seen throughout the remainder of the abdomen or pelvis. Upper thighs also unremarkable. Moderate colonic diverticulosis again seen.

Skeletal: Prominent right hip degenerative changes are seen. Multilevel spinal degenerative changes seen, most advanced within the lower lumbar spine. No evidence of osseous metastatic disease.

Impression:

1. Small amounts of nonspecific uptake along the distal common bile duct, decreased in both amount and degree of activity since prior exam.
2. No evidence to suggest recurrent or metastatic disease otherwise noted.
3. Small hypodensity along the lateral aspect of the right hepatic lobe without associated glucose accumulation is unchanged.
4. Other stable chronic findings are discussed above.

Latest Scan

Source: NCI Genomic Data Commons file 0881ff7c-db51-4415-8ee9-421615fdc164 (ER0493 ER-B055 Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).